Somatic mutation profile of tumor specimen 0DPCXX from CCDI case PBCDLV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.6 years (2,058 days).
Specimen 0DPCXX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b522d90-17b9-425b-9d79-b5bf396deeb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPCXR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b368061-e080-457a-b3a7-7c519fa2c322

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Splice Site 1, Missense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V0D1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 348/890 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374474225; called by muse, mutect2, varscan2
- CLPTM1 | c.1038+8C>T | Splice Region (SNP) | VAF 160/350 reads (46%) | catalogued as rs770087065, COSV100493890; called by muse, mutect2, varscan2
- YTHDC1 | c.1761+1del p.X587_splice (on ENST00000344157 / NM_001031732.4; = p.X569_splice on NM_133370.4) | Splice Site (DEL) | VAF 143/446 reads (32%) | called by mutect2, pindel, varscan2
